Somatic mutation profile of tumor specimen TARGET-20-PASZLJ-09A (aliquot TARGET-20-PASZLJ-09A-01D) from TARGET case TARGET-20-PASZLJ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,543 days).
Specimen TARGET-20-PASZLJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92d3d9a6-e5a7-490a-bed9-dd5302b1ecc9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASZLJ-14A (Bone Marrow Normal), aliquot TARGET-20-PASZLJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b30d9c0b-9966-4200-a6bc-d009d125bb66

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 91/314 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FCGBP | c.7102C>T p.R2368C | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1364093618; called by muse, mutect2
